Somatic mutation profile of tumor specimen TCGA-W5-AA2T-01A (aliquot TCGA-W5-AA2T-01A-12D-A417-09) from TCGA case TCGA-W5-AA2T, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.5 years (23,560 days).
Specimen TCGA-W5-AA2T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37272a92-1ae5-4c5f-adba-1236264aaa14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2T-10A (Blood Derived Normal), aliquot TCGA-W5-AA2T-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3de64427-a1d8-4124-ac02-315860dc8a07

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV55743377; called by muse, mutect2, varscan2
- AR | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV65963967, COSV65964753; called by muse, mutect2, varscan2
- BNC2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs1385446031, COSV66160377; called by muse, mutect2, varscan2
- CHRM2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs143842239, COSV57767125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.5161G>C p.G1721R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV56635600; called by muse, mutect2, varscan2
- ELL2 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); catalogued as COSV52985647; called by muse, mutect2, varscan2
- GPR31 | c.933T>G p.D311E | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64762114; called by muse, mutect2, varscan2
- HAS1 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55790154; called by muse, mutect2, varscan2
- HNRNPUL2 | c.910A>G p.M304V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748960499, COSV57134334; called by muse, mutect2, varscan2
- ICE1 | c.3811C>T p.Q1271* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56833095; called by muse, mutect2, varscan2
- IZUMO2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV53231588; called by muse, mutect2, varscan2
- KLHL25 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV61996772; called by muse, mutect2, varscan2
- LAIR2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV56623220; called by muse, mutect2, varscan2
- MARCHF7 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs149065142; called by muse, mutect2, varscan2
- MRPS27 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs755271237, COSV54654204; called by muse, mutect2, varscan2
- NEIL3 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52809806, COSV52814206; called by muse, mutect2
- OPRD1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV52381888; called by muse, mutect2, varscan2
- REG3G | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.189); catalogued as COSV55452041; called by muse, mutect2, varscan2
- RYR1 | c.8177A>G p.K2726R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV62105081, COSV62112502; called by muse, mutect2
- SMAD5 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.41); catalogued as COSV72597749; called by muse, mutect2
- TNNI3K | c.2252A>G p.N751S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780090120, COSV53953145; called by muse, mutect2, varscan2
- TRIM55 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52551576; called by muse, mutect2, varscan2
- ISL2 | c.557dup p.Q187Afs*98 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- TPTE | c.781A>T p.R261* (on ENST00000618007 / NM_199261.4; = p.R243* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.858C>G p.T286= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs138695820; called by muse, mutect2, varscan2
- CHRM3 | c.1338A>C p.S446= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV55107924; called by muse, mutect2, varscan2
- COL5A1 | c.4371G>A p.P1457= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs756096066, COSV100879604, COSV65667311; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HAPLN3 | c.243G>A p.P81= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1165462965, COSV62086710; called by mutect2, varscan2
- HCN2 | c.1902C>T p.S634= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs752132558, COSV52119415; called by muse, mutect2, varscan2
- HS3ST1 | c.126C>T p.R42= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs778355639, COSV50024385; called by muse, mutect2, varscan2
- ITPRIP | c.1425C>T p.H475= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs778928901, COSV53393320; called by muse, varscan2
- LRRC7 | c.2775T>C p.P925= (on ENST00000651989 / NM_001370785.2; = p.P892= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PODN | c.321C>T p.P107= (on ENST00000395871; = p.P59= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as rs143779530; called by muse, mutect2, varscan2
- SLFN12 | c.543C>T p.A181= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1199208400, COSV59227912; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1221C>T p.Y407= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs369009120; called by muse, mutect2, varscan2
- THSD7B | c.759G>A p.L253= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV55745624, COSV99745779; called by muse, mutect2, varscan2
- ZNF831 | c.3474G>A p.T1158= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs767673212, COSV64038612; called by muse, mutect2, varscan2
- TTN | c.34265-4550G>C | Intron (SNP) | VAF 128/265 reads (48%) | catalogued as COSV100625705, COSV60032991, COSV60398555; called by muse, mutect2, varscan2
